Somatic mutation profile of tumor specimen 0D95II from CCDI case PBBHPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,384 days).
Specimen 0D95II: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a73ba5f3-4a9e-4376-ad05-a9137c3ecd51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D95IK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d984eb79-1000-469c-97ab-60678e2347f6

The open-access MAF lists 15 somatic variants for this specimen: 6 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Missense Mutation 5, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 384/913 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 48/1254 reads (4%) | catalogued as COSV59958339; called by muse, mutect2
- SHTN1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 198/606 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs772447430, COSV53380035; called by muse, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 93/1624 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 39/746 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 64/1050 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 18/130 reads (14%) | called by muse, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 18/134 reads (13%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 56/531 reads (11%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 35/332 reads (11%) | catalogued as rs1415560984; called by mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- SKIDA1 | c.-60G>A | 5'UTR (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 18/408 reads (4%) | catalogued as rs1015442172; called by muse, mutect2
- WTAP | c.87-50T>A | Intron (SNP) | VAF 15/191 reads (8%) | called by mutect2, varscan2
